TCGA case TCGA-04-1346 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Gynecologic Oncology Group. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/25a0a9e6-4f5b-45d8-8f34-abfd31d5ff1b

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 73 years; Vital status: Alive.

Diagnoses (1)
1. Serous cystadenocarcinoma, NOS: ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 73.6 years (26,865 days); Year of diagnosis: 2003; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G2; Prior treatment: No; Days to last follow up: 1,993 days (5.5 years).
   Pathology details: Lymphatic invasion present: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 1,993 days (5.5 years); Disease response: Tumor Free.
- Karnofsky performance status: 100.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-04-1346-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 2; Intermediate dimension: 1.5; Shortest dimension: 0.3.
  Slide TCGA-04-1346-01A-01-BS1: Section location: Bottom; Percent tumor cells: 69; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 30.
  Slide TCGA-04-1346-01A-01-TS1: Section location: Top; Percent tumor cells: 68; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 30.
- Sample TCGA-04-1346-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 2; Intermediate dimension: 1.2; Shortest dimension: 0.1.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: Tumor free; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Lymphovascular invasion indicator: Yes.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free.

The TCGA Pan-Cancer Clinical Data Resource (Liu et al., Cell 2018) lists this case as redacted by TCGA at the time of its curation; its follow-up endpoints are therefore not restated here.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-04-1346-01A-01D-0428-01): tumor purity 0.54, ploidy 3.4, whole-genome doublings 2.
